Somatic mutation profile of tumor specimen MMRF_1683_1_BM_CD138pos (aliquot MMRF_1683_1_BM_CD138pos_T1_KBS5U_L04784) from MMRF case MMRF_1683, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.8 years (26,234 days).
Specimen MMRF_1683_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c6c831f-c493-448c-96bc-bf184f1cb5f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1683_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1683_1_PB_Whole_C3_KBS5U_L04797; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89ce7f62-233d-4f7d-bff0-303297594b74

The open-access MAF lists 556 somatic variants for this specimen: 203 protein-altering or splice-affecting, 67 silent, 286 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, 3'UTR 153, Silent 67, Intron 66, 5'UTR 28, 5'Flank 20, Nonsense Mutation 16, 3'Flank 13, Splice Site 7, RNA 6, Splice Region 5, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE | c.3578G>A p.S1193N | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs780228220; called by muse, mutect2, varscan2
- ANGPT2 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 34/86 reads (40%) | catalogued as COSV100291164; called by muse, mutect2, varscan2
- ANKRD30A | c.751C>T p.H251Y (on ENST00000611781; = p.H195Y on NM_052997.2) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV100652838; called by muse, mutect2, varscan2
- ARHGAP21 | c.4276G>A p.E1426K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs749603047, COSV57603374; called by muse, mutect2, varscan2
- ARHGEF7 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 72/74 reads (97%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1413255015, COSV99055210; called by muse, mutect2, varscan2
- ARSA | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.072); catalogued as rs1220454918; called by muse, mutect2, varscan2
- ATM | c.7267G>A p.E2423K | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs1555122245, COSV53730531; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTN3A3 | c.1588C>T p.H530Y | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99764837; called by muse, mutect2
- C12orf56 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781625732; called by muse, mutect2, varscan2
- C12orf76 | n.381-8del | Splice Region (DEL) | VAF 19/47 reads (40%) | catalogued as rs768731497; called by mutect2, varscan2
- C1orf198 | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 94/435 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV64174473; called by muse, mutect2, varscan2
- CCDC141 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as COSV99836626; called by muse, mutect2, varscan2
- CD2AP | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 104/209 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV63758966; called by muse, mutect2, varscan2
- CDKN1C | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1564930723; called by muse, mutect2, varscan2
- CNTN3 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs373612458, COSV55163418; called by muse, mutect2, varscan2
- CREBBP | c.5782C>T p.Q1928* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | catalogued as COSV52145993; called by muse, mutect2, varscan2
- DNA2 | c.1747G>T p.E583* | Nonsense Mutation (SNP) | VAF 6/96 reads (6%) | catalogued as COSV64427756; called by muse, mutect2
- DNA2 | c.1746G>A p.M582I | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV64428162; called by muse, mutect2
- DOCK4 | c.5611G>A p.E1871K | Missense Mutation (SNP) | VAF 127/296 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as COSV70238571; called by muse, mutect2, varscan2
- EIF3B | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.109); catalogued as rs1014608839; called by muse, mutect2, varscan2
- ERBB4 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 96/208 reads (46%) | catalogued as COSV53507649; called by muse, mutect2, varscan2
- FAT1 | c.10688T>G p.V3563G | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV71675135; called by muse, mutect2, varscan2
- FNBP1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 93/159 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100852733, COSV63086631; called by muse, mutect2, varscan2
- FOCAD | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100620276; called by muse, mutect2, varscan2
- FUT4 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs984644159, COSV62469209, COSV62469259, COSV62470017; called by muse, mutect2, varscan2
- GRB7 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV100485673; called by muse, mutect2, varscan2
- H3C7 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 124/256 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.204); catalogued as COSV55099822, COSV55101039; called by muse, mutect2, varscan2
- HNF4A | c.757C>G p.R253G | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as CM082885; called by muse, mutect2, varscan2
- HNRNPH3 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.461); catalogued as rs1053460043; called by muse, mutect2, varscan2
- IDS | c.95C>G p.S32W | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as CM981009; called by muse, mutect2
- IGHG1 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs764640329; called by muse, mutect2, varscan2
- IGHV1-69D | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 73/327 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as rs1283966798; called by muse, mutect2, varscan2
- IGHV2-70 | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 86/119 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs369592881; called by muse, varscan2
- IGHV2-70 | c.53T>G p.L18* | Nonsense Mutation (SNP) | VAF 107/170 reads (63%) | catalogued as rs546731210; called by muse, varscan2
- IGLV3-1 | c.161A>C p.Y54S | Missense Mutation (SNP) | VAF 47/48 reads (98%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs375251465; called by muse, mutect2, varscan2
- INPP5A | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs1217669601, COSV61248994; called by muse, mutect2, varscan2
- KIAA1328 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs896751335; called by muse, mutect2, varscan2
- KIF26B | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV101313697; called by muse, mutect2, varscan2
- KLHL13 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99452303; called by muse, mutect2
- KLHL41 | c.1377-1G>A p.X459_splice | Splice Site (SNP) | VAF 13/123 reads (11%) | catalogued as rs111476553; called by muse, mutect2, varscan2
- L3MBTL3 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62387748; called by muse, mutect2
- LINGO1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100796527, COSV62436071; called by muse, mutect2
- LMTK3 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1258904960; called by muse, mutect2, varscan2
- MAZ | c.1379C>T p.S460L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.561); catalogued as rs995948460, COSV99360870; called by muse, mutect2, varscan2
- MED18 | c.52A>G p.M18V | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs775712745; called by muse, mutect2, varscan2
- MON2 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 225/460 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1305392295; called by muse, mutect2, varscan2
- MYCBPAP | c.23C>G p.S8C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60412620; called by muse, mutect2, varscan2
- MYLK | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as rs765972446, COSV100659080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO3B | c.2628C>G p.F876L | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV58704203; called by muse, mutect2
- NDST4 | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1382728658; called by muse, mutect2, varscan2
- NF1 | c.205-1G>A p.X69_splice | Splice Site (SNP) | VAF 43/89 reads (48%) | catalogued as CS000866, CS1311497, COSV100647696, COSV62195996, COSV62209211; called by muse, mutect2, varscan2
- NF1 | c.1319G>C p.R440P | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100647812, COSV62201290; called by muse, mutect2, varscan2
- NIBAN1 | c.2741G>A p.G914E | Missense Mutation (SNP) | VAF 176/776 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as rs1458303651, COSV62287636; called by muse, mutect2, varscan2
- NKX2-8 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs753841581, COSV51874244, COSV99352366; called by muse, mutect2, varscan2
- OBSCN | c.9943G>C p.G3315R | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1364770178, COSV52738378; called by muse, mutect2
- PCDH11X | c.3003C>A p.F1001L | Missense Mutation (SNP) | VAF 181/182 reads (99%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV53461038; called by muse, mutect2, varscan2
- PIP5K1A | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.191); catalogued as rs757909566; called by muse, mutect2
- PLEKHH2 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 213/464 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as rs1326941593, COSV56753538; called by muse, mutect2, varscan2
- POLR3E | c.1010C>A p.S337* | Nonsense Mutation (SNP) | VAF 46/96 reads (48%) | catalogued as COSV55401135; called by muse, mutect2, varscan2
- PPP4R4 | c.1002G>C p.L334F | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs887040022, COSV58552822, COSV58554714; called by muse, mutect2
- PRKAG2 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.088); catalogued as rs564358410, COSV55224669; called by muse, mutect2
- PRKAR2A | c.446C>G p.S149C | Missense Mutation (SNP) | VAF 33/299 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs780071307; called by muse, mutect2, varscan2
- PRR14L | c.5825C>T p.T1942M | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs535691979; called by muse, mutect2, varscan2
- PXDNL | c.2139G>T p.R713S | Missense Mutation (SNP) | VAF 109/217 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs754147414, COSV62479678; called by muse, mutect2, varscan2
- RIPK3 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV99353118; called by muse, mutect2
- RNF149 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV54865204; called by muse, mutect2, varscan2
- SF3B1 | c.2352G>A p.M784I | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59226083; called by muse, mutect2, varscan2
- SIGLEC10 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779111009; called by muse, mutect2, varscan2
- SLC7A2 | c.1225G>A p.A409T (on ENST00000494857 / NM_001370338.1; = p.A448T on NM_003046.6) | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); catalogued as COSV50247760; called by muse, mutect2, varscan2
- SOGA1 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 173/304 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs1024131957; called by muse, mutect2, varscan2
- SPATA22 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV52153831; called by muse, mutect2, varscan2
- SSR3 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.436); catalogued as COSV54019953; called by muse, mutect2, varscan2
- TNKS | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.41); catalogued as COSV60056653; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3943C>G p.L1315V | Missense Mutation (SNP) | VAF 92/178 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64099859; called by muse, mutect2, varscan2
- TP53 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as CM044725, COSV52746809, COSV52814837, COSV53366474; called by muse, mutect2, varscan2
- TRPA1 | c.2756G>A p.R919Q | Missense Mutation (SNP) | VAF 130/250 reads (52%) | SIFT tolerated (0.82); PolyPhen benign (0.059); catalogued as rs145505945, COSV100085110; called by muse, mutect2, varscan2
- TUT4 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 114/244 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV57117928; called by muse, mutect2, varscan2
- VWDE | c.1931C>T p.S644L | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1353641240; called by muse, mutect2, varscan2
- WIPF3 | c.502C>G p.R168G | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.238); catalogued as COSV54210529; called by muse, mutect2, varscan2
- ZFHX3 | c.4147G>A p.E1383K | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV99194988, COSV99212558; called by muse, mutect2, varscan2
- ZNF518A | c.3280C>T p.L1094F | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1327984833; called by muse, mutect2, varscan2
- ZNF700 | c.1982C>G p.S661C | Missense Mutation (SNP) | VAF 137/296 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54314077; called by muse, mutect2, varscan2
- ACAN | c.4742C>T p.S1581F | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACTN1 | c.2438T>A p.I813N | Missense Mutation (SNP) | VAF 99/193 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM32 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ADAMTS18 | c.2674+4G>A | Splice Region (SNP) | VAF 40/75 reads (53%) | called by muse, mutect2, varscan2
- ALDH16A1 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALG10B | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- APCDD1L | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 49/96 reads (51%) | called by muse, mutect2, varscan2
- ARID1A | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ATAD2 | c.2884G>T p.A962S | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2
- ATN1 | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BBOX1 | c.220G>T p.V74L | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRICD5 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRWD1 | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C11orf58 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 179/358 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C1QTNF7 | c.243G>T p.L81F | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAT | c.594C>G p.F198L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC62 | c.189G>C p.Q63H | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC88A | c.4673-1G>C p.X1558_splice (on ENST00000436346 / NM_001365480.1; = p.X1530_splice on NM_018084.5) | Splice Site (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- CCSAP | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCT2 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CDH15 | c.433C>G p.Q145E | Missense Mutation (SNP) | VAF 79/145 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CMBL | c.607C>G p.Q203E | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.047); called by muse, mutect2
- COL27A1 | c.4409C>T p.P1470L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- COL6A6 | c.4564G>T p.G1522* | Nonsense Mutation (SNP) | VAF 100/209 reads (48%) | called by muse, mutect2, varscan2
- COL9A3 | c.1603+7C>T | Splice Region (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- CPNE9 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- DDN | c.945G>T p.E315D | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.434); called by muse, mutect2
- DDOST | c.209G>A p.R70Q (on ENST00000415136; = p.R53Q on NM_005216.5) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- DIS3 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 131/136 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH5 | c.3635C>G p.A1212G | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DNAI4 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.192); called by muse, mutect2
- DNAJC2 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- DNASE1L1 | c.526-4C>G | Splice Region (SNP) | VAF 195/212 reads (92%) | called by muse, mutect2, varscan2
- DOK7 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- DPYSL3 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- DSP | c.3861G>C p.K1287N | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- EVPL | c.4715G>A p.R1572K | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM102A | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FANCD2 | c.381G>C p.M127I | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXO3 | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- FRMD6 | c.19C>G p.H7D | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- GJA8 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- GMDS | c.998A>C p.Q333P | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- GNA13 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GUCY2D | c.208C>G p.R70G | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- HSPA6 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- IDI2 | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 32/374 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); called by muse, mutect2
- IGHV2-70D | c.122G>C p.C41S | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- IGHV2-70D | c.47G>C p.W16S | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.691); called by muse, varscan2
- INO80D | c.2974G>A p.D992N | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KAT6B | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 26/381 reads (7%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.015); called by muse, mutect2
- KCNG2 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, varscan2
- KDM2A | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KIAA1549L | c.3874G>C p.E1292Q (on ENST00000321505; = p.E1589Q on NM_012194.3) | Missense Mutation (SNP) | VAF 82/165 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- LOXHD1 | c.3244G>C p.D1082H | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- LPIN2 | c.2690G>C p.*897Sext*25 | Nonstop Mutation (SNP) | VAF 40/70 reads (57%) | called by muse, mutect2, varscan2
- LRRC74A | c.1426G>A p.G476S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- LTBP2 | c.4889-1G>A p.X1630_splice | Splice Site (SNP) | VAF 7/12 reads (58%) | called by muse, varscan2
- LUC7L3 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- LYST | c.4500A>T p.R1500S | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- MAFB | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MAP4 | c.1766T>G p.I589S | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2
- MEFV | c.1141C>G p.Q381E | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- MPL | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.632); called by muse, mutect2
- MTMR1 | c.1934C>T p.S645L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- MTOR | c.4753C>G p.R1585G | Missense Mutation (SNP) | VAF 110/298 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYOF | c.2109-1G>C p.X703_splice | Splice Site (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- NDOR1 | c.1375G>C p.G459R (on ENST00000371521 / NM_001144026.3; = p.G452R on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEB | c.15513C>G p.I5171M | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- NECTIN2 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- NEK9 | c.2586A>C p.K862N | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- NRBP1 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ODF3 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- OR2T27 | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR4Q2 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 237/471 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.2216C>T p.S739F | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- PEG10 | c.484C>T p.Q162* (on ENST00000482108 / NM_001040152.2; = p.Q196* on NM_015068.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 144/259 reads (56%) | called by muse, mutect2, varscan2
- PHLPP1 | c.3240G>C p.M1080I | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- PIP5K1A | c.997G>A p.D333N (on ENST00000368888 / NM_001135638.2; = p.D320N on NM_003557.3) | Missense Mutation (SNP) | VAF 87/348 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- POLR3C | c.336G>C p.L112F | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- PRKDC | c.2918del p.A973Gfs*7 | Frame Shift Del (DEL) | VAF 46/117 reads (39%) | called by mutect2, pindel, varscan2
- QSER1 | c.209G>C p.R70T (on ENST00000399302; = p.R199T on NM_001076786.3) | Missense Mutation (SNP) | VAF 39/249 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- RAB3IP | c.758C>A p.A253D (on ENST00000550536 / NM_175623.4; = p.A237D on NM_022456.5) | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2
- RPL14 | c.156C>G p.F52L | Missense Mutation (SNP) | VAF 5/135 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.388); called by muse, mutect2
- RPS3A | c.54G>C p.K18N | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- RTL1 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- RYR2 | c.2860G>C p.D954H | Missense Mutation (SNP) | VAF 61/287 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SBF1 | c.3030G>C p.Q1010H | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCN9A | c.3348_3351dup p.R1118Sfs*15 (on ENST00000303354; = p.R1107Sfs*15 on NM_002977.3) | Frame Shift Ins (INS) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- SDHC | c.123C>G p.F41L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- SEMA3C | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 136/238 reads (57%) | called by muse, mutect2, varscan2
- SGTA | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIPA1L2 | c.2005C>T p.L669F | Missense Mutation (SNP) | VAF 19/269 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SLCO5A1 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- SLU7 | c.-15G>A | Splice Region (SNP) | VAF 157/331 reads (47%) | called by muse, mutect2, varscan2
- SNX13 | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- SOBP | c.2197G>T p.E733* | Nonsense Mutation (SNP) | VAF 23/46 reads (50%) | called by muse, varscan2
- SPEG | c.542C>G p.S181* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- STARD7 | c.622A>G p.S208G | Missense Mutation (SNP) | VAF 146/300 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- STK36 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.305); called by muse, mutect2
- TACC2 | c.5783G>A p.R1928K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- TAF1L | c.2815C>T p.Q939* | Nonsense Mutation (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- TET1 | c.601A>C p.I201L | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- TIMM44 | c.312+1del p.X104_splice | Splice Site (DEL) | VAF 49/133 reads (37%) | called by mutect2, pindel, varscan2
- TLL2 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- TLNRD1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- TPR | c.6037G>A p.D2013N | Missense Mutation (SNP) | VAF 47/708 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); called by muse, mutect2
- TTN | c.59012C>T p.T19671I (on ENST00000591111; = p.T12247I on NM_003319.4) | Missense Mutation (SNP) | VAF 47/102 reads (46%) | PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TYW3 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- UGGT2 | c.4471T>C p.Y1491H | Missense Mutation (SNP) | VAF 60/64 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP7 | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- VPS13D | c.11977C>T p.P3993S | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- WDR26 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- WDR97 | c.3454G>A p.V1152I | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR97 | c.4069G>T p.E1357* | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- ZBTB9 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- ZCCHC17 | c.226-1G>C p.X76_splice | Splice Site (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- ZFC3H1 | c.44C>G p.S15W | Missense Mutation (SNP) | VAF 20/367 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- ZFHX4 | c.9316C>G p.P3106A | Missense Mutation (SNP) | VAF 11/290 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF229 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); called by muse, mutect2
- ZNF775 | c.1262G>C p.R421P | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADI1 | c.531G>A p.Q177= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs1458794433; called by muse, mutect2
- AHNAK | c.13404G>C p.L4468= | Silent (SNP) | VAF 69/173 reads (40%) | called by muse, mutect2, varscan2
- AIFM1 | c.90G>A p.Q30= | Silent (SNP) | VAF 58/62 reads (94%) | catalogued as COSV54852748; called by muse, mutect2, varscan2
- ALCAM | c.24C>T p.S8= | Silent (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- ANKRD60 | c.240G>A p.P80= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- BEST3 | c.1632C>T p.G544= | Silent (SNP) | VAF 60/123 reads (49%) | catalogued as COSV58298693; called by muse, mutect2, varscan2
- BMF | c.132C>T p.L44= | Silent (SNP) | VAF 78/138 reads (57%) | called by muse, mutect2, varscan2
- C15orf39 | c.39G>A p.V13= | Silent (SNP) | VAF 42/87 reads (48%) | called by muse, mutect2, varscan2
- C17orf97 | c.606C>G p.L202= | Silent (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- CARS1 | c.2229G>A p.Q743= | Silent (SNP) | VAF 22/321 reads (7%) | called by muse, mutect2
- CCDC88C | c.345G>A p.K115= | Silent (SNP) | VAF 103/193 reads (53%) | catalogued as COSV66236594; called by muse, mutect2, varscan2
- CD200R1 | c.744C>T p.I248= (on ENST00000471858 / NM_170780.3; = p.I271= on NM_138806.4) | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs1378548073, COSV99867981; called by muse, mutect2, varscan2
- CDH11 | c.1950C>T p.V650= | Silent (SNP) | VAF 137/310 reads (44%) | called by muse, mutect2, varscan2
- CEP57L1 | c.324G>C p.L108= | Silent (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2
- COQ3 | c.522C>T p.I174= | Silent (SNP) | VAF 115/226 reads (51%) | catalogued as rs774361147, COSV54640109; called by muse, mutect2, varscan2
- DHODH | c.510C>T p.L170= | Silent (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- ERV3-1 | c.1704C>T p.F568= | Silent (SNP) | VAF 107/258 reads (41%) | catalogued as rs1178152676; called by muse, mutect2, varscan2
- EXTL1 | c.1257C>T p.F419= | Silent (SNP) | VAF 52/125 reads (42%) | called by muse, mutect2, varscan2
- FEM1A | c.1845G>A p.K615= | Silent (SNP) | VAF 19/30 reads (63%) | called by muse, mutect2, varscan2
- FOXA1 | c.408G>A p.P136= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs761859305; called by muse, mutect2
- GJB7 | c.609C>G p.L203= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as rs959181572; called by muse, mutect2, varscan2
- GPR180 | c.1044G>A p.E348= | Silent (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
- GRIA4 | c.72G>A p.P24= | Silent (SNP) | VAF 56/59 reads (95%) | catalogued as rs957571829, COSV56915495; called by muse, mutect2, varscan2
- HCN3 | c.1323C>T p.L441= | Silent (SNP) | VAF 13/131 reads (10%) | catalogued as rs1207946311; called by muse, mutect2, varscan2
- IPO4 | c.3187C>T p.L1063= | Silent (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- ISY1 | c.717C>T p.F239= | Silent (SNP) | VAF 29/168 reads (17%) | called by muse, mutect2, varscan2
- KCNA6 | c.231C>T p.F77= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV54976894; called by muse, mutect2, varscan2
- KCNG1 | c.735C>T p.S245= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as rs772722108; called by muse, mutect2, varscan2
- L3MBTL3 | c.48C>T p.F16= | Silent (SNP) | VAF 99/541 reads (18%) | catalogued as COSV62386598; called by muse, mutect2, varscan2
- LDHAL6B | c.192G>A p.E64= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs1428494212, COSV55684303; called by muse, mutect2, varscan2
- LIN54 | c.582G>C p.V194= | Silent (SNP) | VAF 22/133 reads (17%) | catalogued as rs772875070; called by muse, mutect2, varscan2
- LTB4R2 | c.402C>T p.L134= (on ENST00000528054; = p.L103= on NM_019839.5) | Silent (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2, varscan2
- MAGEH1 | c.522G>A p.L174= | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as COSV61678647; called by muse, mutect2, varscan2
- MAST1 | c.3882C>T p.F1294= | Silent (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2, varscan2
- MED12L | c.6130C>T p.L2044= | Silent (SNP) | VAF 41/93 reads (44%) | called by muse, mutect2, varscan2
- MFSD9 | c.624C>T p.F208= | Silent (SNP) | VAF 50/122 reads (41%) | called by muse, mutect2, varscan2
- MINDY3 | c.12G>A p.L4= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as rs749646754; called by muse, mutect2, varscan2
- MTR | c.3255C>T p.F1085= | Silent (SNP) | VAF 30/318 reads (9%) | called by muse, mutect2
- MUC12 | c.16341G>A p.E5447= (on ENST00000379442; = p.E5304= on NM_001164462.1) | Silent (SNP) | VAF 82/150 reads (55%) | called by muse, mutect2, varscan2
- MYBPH | c.72G>T p.V24= | Silent (SNP) | VAF 16/240 reads (7%) | catalogued as COSV99704083; called by muse, mutect2
- NEK8 | c.756C>A p.I252= | Silent (SNP) | VAF 8/113 reads (7%) | called by muse, mutect2
- NES | c.2847G>A p.Q949= | Silent (SNP) | VAF 96/920 reads (10%) | called by muse, mutect2, varscan2
- NLRP9 | c.2127G>A p.L709= | Silent (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- OR51I2 | c.576C>A p.I192= | Silent (SNP) | VAF 142/290 reads (49%) | catalogued as COSV58299123; called by muse, mutect2, varscan2
- PABPC3 | c.630C>G p.L210= | Silent (SNP) | VAF 68/102 reads (67%) | catalogued as rs1279662656; called by muse, varscan2
- PAX7 | c.1431G>C p.V477= | Silent (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.435G>A p.V145= | Silent (SNP) | VAF 84/173 reads (49%) | catalogued as COSV53892302; called by muse, mutect2, varscan2
- PLEKHM1 | c.2781C>T p.L927= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs1462142613; called by muse, mutect2, varscan2
- PSEN2 | c.243C>T p.L81= | Silent (SNP) | VAF 30/132 reads (23%) | called by muse, mutect2, varscan2
- PWWP3A | c.2198G>A p.*733= (on ENST00000627377; = p.E680K on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV60904608; called by muse, mutect2, varscan2
- RIPOR3 | c.765C>T p.F255= | Silent (SNP) | VAF 111/242 reads (46%) | called by muse, mutect2, varscan2
- RNF216 | c.945G>C p.L315= (on ENST00000425013 / NM_207116.3; = p.L372= on NM_207111.4) | Silent (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- RTN1 | c.2310C>T p.G770= | Silent (SNP) | VAF 86/180 reads (48%) | catalogued as rs774464763, COSV50720413; called by muse, mutect2, varscan2
- RXRG | c.489C>T p.F163= | Silent (SNP) | VAF 23/209 reads (11%) | catalogued as COSV63233114; called by muse, mutect2, varscan2
- RYR1 | c.12414C>T p.I4138= | Silent (SNP) | VAF 72/149 reads (48%) | catalogued as COSV62113898; called by muse, mutect2, varscan2
- SDHA | c.786C>G p.T262= | Silent (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- SLC11A1 | c.1107G>A p.L369= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as rs753572209; called by muse, mutect2, varscan2
- SMOC2 | c.1227G>A p.L409= (on ENST00000356284 / NM_001166412.2; = p.L420= on NM_022138.3) | Silent (SNP) | VAF 71/143 reads (50%) | called by muse, mutect2, varscan2
- SORD | c.963C>A p.L321= | Silent (SNP) | VAF 26/67 reads (39%) | called by muse, varscan2
- SOX15 | c.507G>T p.S169= | Silent (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- SPEG | c.465C>T p.F155= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs763987828; called by muse, varscan2
- UAP1 | c.288C>T p.F96= | Silent (SNP) | VAF 52/195 reads (27%) | called by muse, mutect2, varscan2
- UBFD1 | c.780C>T p.V260= | Silent (SNP) | VAF 43/96 reads (45%) | called by muse, mutect2, varscan2
- UNC13D | c.3207C>G p.V1069= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs771349798; called by muse, mutect2, varscan2
- UPP2 | c.39A>G p.E13= | Silent (SNP) | VAF 110/237 reads (46%) | called by muse, mutect2, varscan2
- WDR81 | c.909G>C p.L303= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs1398433929; called by muse, mutect2, varscan2
- ZNF671 | c.447A>G p.A149= | Silent (SNP) | VAF 50/107 reads (47%) | called by muse, mutect2, varscan2
- AC005324.2 | c.*1390C>G | 3'UTR (SNP) | VAF 35/104 reads (34%) | called by muse, mutect2, varscan2
- AC024651.2 | chr15:97875041 C>A | 5'Flank (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- AC084082.1 | n.128C>T | RNA (SNP) | VAF 26/52 reads (50%) | catalogued as rs957761831; called by muse, mutect2, varscan2
- AC104057.1 | n.70C>G | RNA (SNP) | VAF 63/130 reads (48%) | called by muse, mutect2, varscan2
- AC114490.3 | c.*723C>T | 3'UTR (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- ACAD8 | c.-15G>A | 5'UTR (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- ACP3 | c.*977G>A | 3'UTR (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2
- ACSL6 | chr5:131950746 G>C | 3'Flank (SNP) | VAF 20/157 reads (13%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.*1218G>A | 3'UTR (SNP) | VAF 37/72 reads (51%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.3089-72G>A | Intron (SNP) | VAF 24/45 reads (53%) | catalogued as rs922829240; called by muse, mutect2
- ADPGK | chr15:72784006 C>T | 5'Flank (SNP) | VAF 23/156 reads (15%) | catalogued as rs1395769637; called by muse, mutect2, varscan2
- ADSS2 | c.*414C>A | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- AFF2 | c.*8595G>A | 3'UTR (SNP) | VAF 4/25 reads (16%) | catalogued as rs1557294007; called by muse, mutect2, varscan2
- AGO1 | c.-109G>A | 5'UTR (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- AHNAK | c.1-178G>A | Intron (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- AKIRIN1 | c.*1429G>A | 3'UTR (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- ALDH1A3 | c.*169C>T | 3'UTR (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- ALDH5A1 | c.*1314G>A | 3'UTR (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- AMACR | c.*2844T>G | 3'UTR (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- AMPH | c.1182+1275G>A | Intron (SNP) | VAF 41/213 reads (19%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503921 C>T | 5'Flank (SNP) | VAF 74/151 reads (49%) | catalogued as rs745705097; called by muse, mutect2, varscan2
- APEH | c.443-24C>T | Intron (SNP) | VAF 60/114 reads (53%) | called by muse, mutect2, varscan2
- AQP1 | c.*1378C>T | 3'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- AQP6 | c.*268C>A | 3'UTR (SNP) | VAF 11/18 reads (61%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.*191C>T | 3'UTR (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- ARHGEF38 | c.*1466C>T | 3'UTR (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- ARHGEF4 | chr2:130915787 G>A | 5'Flank (SNP) | VAF 41/86 reads (48%) | catalogued as rs986148048; called by muse, mutect2, varscan2
- ARMC1 | c.*1343G>T | 3'UTR (SNP) | VAF 45/104 reads (43%) | called by muse, mutect2, varscan2
- ARMCX1 | c.*63C>T | 3'UTR (SNP) | VAF 40/40 reads (100%) | catalogued as COSV100863167, COSV100863175; called by muse, mutect2, varscan2
- ASH1L | c.-532C>T | 5'UTR (SNP) | VAF 58/256 reads (23%) | called by muse, mutect2, varscan2
- ATF7IP | c.3280+14C>T | Intron (SNP) | VAF 14/23 reads (61%) | called by muse, mutect2, varscan2
- ATP2C1 | c.*914C>G | 3'UTR (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- ATP6V1B2 | c.137-433G>A | Intron (SNP) | VAF 62/157 reads (39%) | catalogued as rs766833344; called by muse, mutect2, varscan2
- ATRIP | c.*130T>G | 3'UTR (SNP) | VAF 49/101 reads (49%) | called by muse, mutect2, varscan2
- B4GALT5 | c.*2653G>A | 3'UTR (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- BAG5 | c.-29+624T>C | Intron (SNP) | VAF 49/108 reads (45%) | called by muse, mutect2, varscan2
- BARX1 | c.-1G>A | 5'UTR (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021352 A>T | 5'Flank (SNP) | VAF 58/109 reads (53%) | called by muse, mutect2, varscan2
- BEND4 | c.*5904G>A | 3'UTR (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- BROX | c.*1473G>A | 3'UTR (SNP) | VAF 82/331 reads (25%) | called by muse, mutect2, varscan2
- C14orf93 | c.*99C>G | 3'UTR (SNP) | VAF 19/96 reads (20%) | called by muse, mutect2, varscan2
- C2orf69 | c.*1291T>C | 3'UTR (SNP) | VAF 59/133 reads (44%) | called by muse, mutect2, varscan2
- CADM1 | chr11:115504457 G>T | 5'Flank (SNP) | VAF 64/135 reads (47%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.181-1991G>A | Intron (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- CARD14 | c.1594+16C>G | Intron (SNP) | VAF 59/138 reads (43%) | called by muse, mutect2, varscan2
- CARD8 | c.351-782G>T | Intron (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- CAV1 | c.30+112C>T | Intron (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- CBFB | c.*1656G>C | 3'UTR (SNP) | VAF 80/154 reads (52%) | called by muse, mutect2, varscan2
- CCDC141 | c.4325+1080T>C | Intron (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- CCNL1 | chr3:157160668 G>C | 5'Flank (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- CCNT2 | c.*2398C>A | 3'UTR (SNP) | VAF 55/114 reads (48%) | called by muse, mutect2, varscan2
- CDHR5 | c.*533G>C | 3'UTR (SNP) | VAF 78/173 reads (45%) | called by muse, mutect2, varscan2
- CDHR5 | chr11:625165 G>A | 5'Flank (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- CDK2 | c.*507C>G | 3'UTR (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- CDR1 | chrX:140783565 C>T | 3'Flank (SNP) | VAF 169/178 reads (95%) | catalogued as rs1569357693, COSV100983392; called by muse, mutect2, varscan2
- CEND1 | chr11:783809 C>G | 3'Flank (SNP) | VAF 33/190 reads (17%) | catalogued as rs1459236856; called by muse, mutect2, varscan2
- CEP126 | c.*2021C>T | 3'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- CEP128 | c.*814C>T | 3'UTR (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- CEP152 | c.4093+230G>A | Intron (SNP) | VAF 50/114 reads (44%) | called by muse, mutect2, varscan2
- CFAP65 | c.542+398T>A | Intron (SNP) | VAF 39/72 reads (54%) | called by muse, mutect2, varscan2
- CGGBP1 | c.*726G>C | 3'UTR (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- CIAPIN1 | chr16:57447405 G>C | 5'Flank (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- CNTF | c.*398G>A | 3'UTR (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- CNTN4 | c.*582G>C | 3'UTR (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- COG1 | c.2511-60C>T | Intron (SNP) | VAF 38/70 reads (54%) | called by mutect2, varscan2
- COPB1 | c.2646+73C>T | Intron (SNP) | VAF 12/60 reads (20%) | catalogued as rs1268455542; called by muse, mutect2, varscan2
- COPS8 | chr2:237085745 G>A | 5'Flank (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- CRAT | c.*204G>T | 3'UTR (SNP) | VAF 47/116 reads (41%) | called by muse, mutect2, varscan2
- CRTC2 | c.998-68C>G | Intron (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2
- CUL5 | c.*2592C>T | 3'UTR (SNP) | VAF 4/46 reads (9%) | catalogued as rs1419842494; called by muse, mutect2
- DARS2 | c.*739G>A | 3'UTR (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- DCAF5 | c.*2874C>T | 3'UTR (SNP) | VAF 24/124 reads (19%) | called by muse, mutect2, varscan2
- DCDC2 | c.*1929G>A | 3'UTR (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- DDR1 | c.*147G>A | 3'UTR (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- DDX59 | chr1:200641254 C>G | 3'Flank (SNP) | VAF 64/261 reads (25%) | called by muse, mutect2, varscan2
- DEPDC1 | chr1:68497185 G>A | 5'Flank (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- DIO2 | c.*825G>T | 3'UTR (SNP) | VAF 60/114 reads (53%) | called by muse, mutect2, varscan2
- DIS3 | c.*419C>T | 3'UTR (SNP) | VAF 64/69 reads (93%) | called by muse, mutect2, varscan2
- DKK2 | c.*679C>T | 3'UTR (SNP) | VAF 16/109 reads (15%) | called by muse, mutect2, varscan2
- DLC1 | c.1567-24A>G | Intron (SNP) | VAF 48/91 reads (53%) | called by muse, mutect2, varscan2
- DNAJC5 | c.*3347C>T | 3'UTR (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- DPF3 | c.871+3039C>T | Intron (SNP) | VAF 80/164 reads (49%) | catalogued as rs375726020; called by muse, varscan2
- DR1 | chr1:93362272 G>A | 3'Flank (SNP) | VAF 57/136 reads (42%) | called by muse, mutect2, varscan2
- DYNAP | c.*214C>T | 3'UTR (SNP) | VAF 27/197 reads (14%) | called by muse, mutect2, varscan2
- EED | c.635-199dup | Intron (INS) | VAF 12/14 reads (86%) | catalogued as rs1011992177; called by mutect2, varscan2
- EFHC1 | c.1640+131G>C | Intron (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- EHD4 | c.*1534G>A | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- EIF2B1 | c.*732G>A | 3'UTR (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- EIF4E | c.*4716C>G | 3'UTR (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- ENPP4 | c.*2201G>C | 3'UTR (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- EPDR1 | c.-297G>A | 5'UTR (SNP) | VAF 144/326 reads (44%) | catalogued as COSV52262226; called by muse, mutect2, varscan2
- EPN2 | c.*188C>A | 3'UTR (SNP) | VAF 110/252 reads (44%) | called by muse, mutect2, varscan2
- ESRRG | c.*2372A>G | 3'UTR (SNP) | VAF 68/249 reads (27%) | called by muse, varscan2
- ETNK1 | c.*501G>A | 3'UTR (SNP) | VAF 21/91 reads (23%) | called by muse, mutect2, varscan2
- EVI5 | c.*1211T>A | 3'UTR (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- EXOC3L1 | c.-7-43C>G | Intron (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- EXOSC4 | c.172-69G>C | Intron (SNP) | VAF 23/130 reads (18%) | called by muse, mutect2, varscan2
- EXPH5 | c.*2107C>G | 3'UTR (SNP) | VAF 15/167 reads (9%) | called by muse, mutect2
- FAM163A | c.*390G>A | 3'UTR (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- FAM53B | c.*3810G>C | 3'UTR (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- FBXW5 | c.1097-104C>T | Intron (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- FIGN | c.*4665C>G | 3'UTR (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- FMO5 | c.*409C>G | 3'UTR (SNP) | VAF 125/262 reads (48%) | called by muse, mutect2, varscan2
- FN1 | c.*959G>A | 3'UTR (SNP) | VAF 39/101 reads (39%) | called by muse, mutect2, varscan2
- FNIP2 | c.*1626G>C | 3'UTR (SNP) | VAF 45/121 reads (37%) | called by muse, mutect2, varscan2
- FRAT1 | c.*1414G>A | 3'UTR (SNP) | VAF 55/113 reads (49%) | called by muse, mutect2, varscan2
- GCN1 | c.3441-51C>T | Intron (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- GID4 | c.*2678C>G | 3'UTR (SNP) | VAF 59/107 reads (55%) | called by muse, mutect2, varscan2
- GOLGA8B | c.*961G>T | 3'UTR (SNP) | VAF 22/105 reads (21%) | called by muse, varscan2
- H1-4 | c.-20C>T | 5'UTR (SNP) | VAF 5/44 reads (11%) | catalogued as rs2298089, COSV56800200, COSV56800639; called by muse, mutect2
- HACE1 | c.*689C>T | 3'UTR (SNP) | VAF 27/169 reads (16%) | called by muse, mutect2, varscan2
- HCRTR2 | c.-198T>A | 5'UTR (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- HEYL | c.*300C>G | 3'UTR (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- HLA-DQB1 | c.797-111C>G | Intron (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- HLX | c.772+167C>T | Intron (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- HMGA2 | c.283-4584C>T | Intron (SNP) | VAF 51/116 reads (44%) | called by muse, mutect2, varscan2
- HNRNPA2B1 | c.6+21G>C | Intron (SNP) | VAF 30/314 reads (10%) | called by muse, mutect2
- HOXA3 | chr7:27106980 C>T | 3'Flank (SNP) | VAF 28/214 reads (13%) | called by muse, mutect2, varscan2
- HOXD8 | c.*626C>T | 3'UTR (SNP) | VAF 6/115 reads (5%) | called by muse, mutect2
- HSPA4 | c.-167C>G | 5'UTR (SNP) | VAF 9/28 reads (32%) | catalogued as rs1339105059; called by muse, mutect2, varscan2
- IFT140 | c.-32+565C>T | Intron (SNP) | VAF 4/19 reads (21%) | catalogued as rs1474151774; called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863420 C>G | 5'Flank (SNP) | VAF 7/16 reads (44%) | called by muse, varscan2
- IL6R | c.949+1388C>T | Intron (SNP) | VAF 20/98 reads (20%) | called by muse, mutect2, varscan2
- INPP4B | c.*411G>A | 3'UTR (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- IP6K2 | c.202+612G>C | Intron (SNP) | VAF 203/521 reads (39%) | called by muse, mutect2, varscan2
- ITCH | chr20:34511050 G>T | 3'Flank (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- KCMF1 | c.*1586C>A | 3'UTR (SNP) | VAF 63/139 reads (45%) | called by muse, mutect2, varscan2
- KCTD11 | c.*613C>T | 3'UTR (SNP) | VAF 14/115 reads (12%) | catalogued as rs1286069271; called by muse, mutect2, varscan2
- KCTD15 | c.*94G>A | 3'UTR (SNP) | VAF 48/93 reads (52%) | catalogued as rs1476917494; called by muse, mutect2, varscan2
- KHDRBS2 | c.*338A>T | 3'UTR (SNP) | VAF 38/69 reads (55%) | called by muse, mutect2, varscan2
- KLHL42 | c.*3094G>A | 3'UTR (SNP) | VAF 19/167 reads (11%) | called by muse, mutect2, varscan2
- KRT4 | c.*396C>T | 3'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- KRTAP10-5 | c.*11C>G | 3'UTR (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- LAMC2 | c.*1517C>A | 3'UTR (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2
- LBHD1 | c.617-452G>C | Intron (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- LCE2B | c.*38G>C | 3'UTR (SNP) | VAF 8/177 reads (5%) | called by muse, mutect2
- LIFR | c.*3867G>A | 3'UTR (SNP) | VAF 7/104 reads (7%) | catalogued as rs1484400949; called by muse, mutect2
- LINC01098 | n.738G>A | RNA (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- LINC02693 | n.5027A>C | RNA (SNP) | VAF 70/344 reads (20%) | called by muse, mutect2, varscan2
- LMNB1 | c.-132C>T | 5'UTR (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- LPAR4 | c.*35C>G | 3'UTR (SNP) | VAF 39/39 reads (100%) | catalogued as COSV101425181; called by muse, mutect2, varscan2
- LRAT | c.*3790C>T | 3'UTR (SNP) | VAF 50/95 reads (53%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.249+18C>T | Intron (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- LYRM4 | c.-38C>T | 5'UTR (SNP) | VAF 109/230 reads (47%) | called by muse, mutect2, varscan2
- MAPRE2 | c.*2345G>A | 3'UTR (SNP) | VAF 44/99 reads (44%) | called by muse, mutect2, varscan2
- MCF2L2 | c.*636C>G | 3'UTR (SNP) | VAF 128/264 reads (48%) | called by muse, mutect2, varscan2
- MEIS1 | c.1024+250T>C | Intron (SNP) | VAF 37/69 reads (54%) | called by muse, mutect2, varscan2
- MIA3 | c.3478-1206G>T | Intron (SNP) | VAF 60/233 reads (26%) | catalogued as COSV60513731; called by muse, mutect2, varscan2
- MIR4710 | chr14:104681270 C>T | 5'Flank (SNP) | VAF 41/77 reads (53%) | called by muse, mutect2, varscan2
- MIR7162 | chr10:30365231 C>T | 3'Flank (SNP) | VAF 72/170 reads (42%) | catalogued as rs1158862371; called by muse, mutect2, varscan2
- MIRLET7A3 | chr22:46110544 G>C | 5'Flank (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- MROH2A | c.-60C>T | 5'UTR (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- MRPL40 | c.-190G>A | 5'UTR (SNP) | VAF 19/21 reads (90%) | called by muse, mutect2, varscan2
- MTR | c.*5243C>T | 3'UTR (SNP) | VAF 14/272 reads (5%) | called by muse, mutect2
- MTSS1 | c.*2022G>A | 3'UTR (SNP) | VAF 46/89 reads (52%) | called by muse, mutect2, varscan2
- MUC15 | c.*70C>G | 3'UTR (SNP) | VAF 85/177 reads (48%) | called by muse, mutect2, varscan2
- NAA11 | c.-135C>T | 5'UTR (SNP) | VAF 12/79 reads (15%) | catalogued as rs1417873602; called by muse, mutect2, varscan2
- NAALAD2 | c.1278+548G>A | Intron (SNP) | VAF 14/16 reads (88%) | called by muse, mutect2, varscan2
- NANP | c.*205T>A | 3'UTR (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- NDUFB4 | c.328-375G>A | Intron (SNP) | VAF 44/102 reads (43%) | called by muse, varscan2
- NFYB | c.*1915C>T | 3'UTR (SNP) | VAF 52/121 reads (43%) | called by muse, mutect2, varscan2
- NIPAL3 | c.*1607C>T | 3'UTR (SNP) | VAF 31/64 reads (48%) | catalogued as rs756250020; called by muse, mutect2, varscan2
- NR1D2 | c.-281C>T | 5'UTR (SNP) | VAF 11/28 reads (39%) | catalogued as rs1226849366; called by muse, mutect2, varscan2
- NSUN5 | chr7:73303111 G>C | 3'Flank (SNP) | VAF 76/171 reads (44%) | called by muse, mutect2, varscan2
- OBSCN | c.5138-50G>A | Intron (SNP) | VAF 11/50 reads (22%) | catalogued as rs555771070; called by muse, mutect2, varscan2
- OGA | c.-267C>T | 5'UTR (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*7539C>T | 3'UTR (SNP) | VAF 47/104 reads (45%) | called by muse, mutect2, varscan2
- OPALIN | chr10:96359309 C>T | 5'Flank (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- OR2U2P | n.799A>G | RNA (SNP) | VAF 92/190 reads (48%) | called by muse, mutect2, varscan2
- OTP | c.-94C>T | 5'UTR (SNP) | VAF 18/140 reads (13%) | catalogued as COSV100119898; called by muse, mutect2, varscan2
- OXSM | chr3:25789818 C>T | 5'Flank (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- PDCD2 | c.658+362C>G | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- PDZD2 | c.477-46905G>A | Intron (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- PDZRN3 | chr3:73624966 C>T | 5'Flank (SNP) | VAF 45/88 reads (51%) | called by muse, mutect2, varscan2
- PEPD | c.671+79G>A | Intron (SNP) | VAF 27/54 reads (50%) | catalogued as rs1167896245; called by muse, mutect2, varscan2
- PHC1P1 | n.26C>A | RNA (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- PHF6 | c.*3205C>G | 3'UTR (SNP) | VAF 54/55 reads (98%) | called by muse, mutect2, varscan2
- PIGK | c.*821C>T | 3'UTR (SNP) | VAF 41/88 reads (47%) | catalogued as rs1193450603; called by muse, mutect2, varscan2
- PIGQ | c.-9-1488G>A | Intron (SNP) | VAF 46/97 reads (47%) | catalogued as rs1157294127; called by muse, mutect2, varscan2
- PIP4K2B | c.*1365C>G | 3'UTR (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- PIP4K2B | c.*1098C>G | 3'UTR (SNP) | VAF 12/103 reads (12%) | catalogued as rs777613813; called by muse, mutect2, varscan2
- PKDREJ | c.*731A>T | 3'UTR (SNP) | VAF 75/147 reads (51%) | called by muse, mutect2, varscan2
- PLAC8L1 | c.-129C>T | 5'UTR (SNP) | VAF 22/120 reads (18%) | called by mutect2, varscan2
- PLCXD2 | c.-26G>A | 5'UTR (SNP) | VAF 78/145 reads (54%) | catalogued as rs1362656325; called by muse, mutect2, varscan2
- PNKP | c.151+122C>G | Intron (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- PPARGC1A | c.*3092C>T | 3'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- PPARGC1B | c.*3362C>G | 3'UTR (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- PPP1R12A | c.*1644G>A | 3'UTR (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- PRKRIP1 | c.*62G>A | 3'UTR (SNP) | VAF 21/52 reads (40%) | called by muse, varscan2
- PRKRIP1 | c.*609A>C | 3'UTR (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- PRKRIP1 | c.*714A>C | 3'UTR (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- PSMA1 | c.-69G>A | 5'UTR (SNP) | VAF 73/147 reads (50%) | called by muse, mutect2, varscan2
- RAB11A | c.*1550T>G | 3'UTR (SNP) | VAF 12/70 reads (17%) | called by mutect2, varscan2
- RAB2A | c.*1633T>G | 3'UTR (SNP) | VAF 38/78 reads (49%) | called by muse, mutect2, varscan2
- RAD21 | chr8:116874972 G>C | 5'Flank (SNP) | VAF 35/89 reads (39%) | catalogued as rs1373396561; called by muse, mutect2, varscan2
- RAD23B | c.*911C>T | 3'UTR (SNP) | VAF 55/119 reads (46%) | called by muse, mutect2, varscan2
- RCCD1 | c.*602C>T | 3'UTR (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- RFT1 | c.*1474C>G | 3'UTR (SNP) | VAF 17/86 reads (20%) | called by muse, varscan2
- RFT1 | c.*1400C>G | 3'UTR (SNP) | VAF 16/92 reads (17%) | called by muse, varscan2
- RNASE11 | chr14:20583583 C>G | 3'Flank (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- RND3 | c.*1533G>C | 3'UTR (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- RNF216 | c.874-138G>C | Intron (SNP) | VAF 69/154 reads (45%) | called by muse, mutect2, varscan2
- RPL41 | chr12:56117899 C>G | 3'Flank (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- RPS23 | c.*252G>C | 3'UTR (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- RTCA | c.146+174G>A | Intron (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- RTF2 | c.*487G>A | 3'UTR (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- SEC61A2 | c.463-1979C>T | Intron (SNP) | VAF 108/269 reads (40%) | called by muse, mutect2, varscan2
- SETD7 | c.*4651C>T | 3'UTR (SNP) | VAF 6/95 reads (6%) | catalogued as rs1372052773; called by muse, mutect2
- SEZ6L | c.*2367G>C | 3'UTR (SNP) | VAF 40/45 reads (89%) | called by muse, mutect2, varscan2
- SGPP2 | c.*489C>G | 3'UTR (SNP) | VAF 5/102 reads (5%) | called by muse, mutect2
- SH3BP5L | c.*75C>T | 3'UTR (SNP) | VAF 23/103 reads (22%) | called by muse, mutect2, varscan2
- SHF | c.303+94C>T | Intron (SNP) | VAF 16/29 reads (55%) | catalogued as rs956639038; called by muse, mutect2, varscan2
- SHLD2 | c.1964-4085G>C | Intron (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- SIKE1 | c.*1881G>A | 3'UTR (SNP) | VAF 32/177 reads (18%) | called by muse, mutect2, varscan2
- SLC18A3 | c.-72C>G | 5'UTR (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- SLC26A4 | c.*2196G>C | 3'UTR (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- SLC30A1 | c.-127C>T | 5'UTR (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2
- SLC38A2 | c.117-113G>C | Intron (SNP) | VAF 54/101 reads (53%) | called by muse, mutect2, varscan2
- SLC41A1 | c.*1656C>T | 3'UTR (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2, varscan2
- SLC41A1 | c.*1222G>A | 3'UTR (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- SLC6A11 | c.623+1921A>G | Intron (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- SMAD9 | c.*19C>T | 3'UTR (SNP) | VAF 31/207 reads (15%) | called by muse, mutect2, varscan2
- SMYD2 | c.*329T>C | 3'UTR (SNP) | VAF 34/163 reads (21%) | catalogued as rs546147161; called by muse, mutect2, varscan2
- SNORA9 | chr7:44985631 C>T | 5'Flank (SNP) | VAF 25/52 reads (48%) | catalogued as rs945003984; called by muse, mutect2, varscan2
- SOCS2 | c.139+489G>A | Intron (SNP) | VAF 47/91 reads (52%) | called by muse, mutect2, varscan2
- SOX6 | chr11:15972364 C>T | 3'Flank (SNP) | VAF 16/71 reads (23%) | catalogued as rs973300812; called by muse, mutect2, varscan2
- SPEG | c.389-713C>G | Intron (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2
- SPN | c.*1640C>G | 3'UTR (SNP) | VAF 6/19 reads (32%) | catalogued as rs1232276272; called by muse, mutect2, varscan2
- SPRR3 | c.*262G>A | 3'UTR (SNP) | VAF 33/124 reads (27%) | called by muse, mutect2, varscan2
- SPRY4 | c.*1276G>A | 3'UTR (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- SRC | c.*941G>A | 3'UTR (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- SRF | c.*868G>C | 3'UTR (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- SRSF11 | c.-25-70C>T | Intron (SNP) | VAF 119/231 reads (52%) | catalogued as rs1043487019; called by muse, mutect2, varscan2
- SSBP2 | c.*7236A>G | 3'UTR (SNP) | VAF 56/110 reads (51%) | catalogued as rs879386899; called by muse, mutect2, varscan2
- SSR2 | c.*389G>A | 3'UTR (SNP) | VAF 37/123 reads (30%) | catalogued as rs763225539; called by muse, mutect2, varscan2
- ST3GAL1 | c.-169A>T | 5'UTR (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- ST6GAL1 | c.*2206C>G | 3'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2
- STAT3 | c.2144+75G>A | Intron (SNP) | VAF 4/97 reads (4%) | catalogued as rs1482609408; called by muse, mutect2
- STRN | c.*3675C>T | 3'UTR (SNP) | VAF 42/99 reads (42%) | called by muse, mutect2, varscan2
- STS | c.*972G>A | 3'UTR (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- SUSD4 | c.*977T>C | 3'UTR (SNP) | VAF 25/221 reads (11%) | catalogued as rs1442134698; called by muse, mutect2, varscan2
- SUSD5 | c.*1590A>T | 3'UTR (SNP) | VAF 48/90 reads (53%) | called by muse, mutect2
- TBCA | c.246+470C>T | Intron (SNP) | VAF 27/48 reads (56%) | called by muse, mutect2, varscan2
- TCF12 | c.-22-97C>T | Intron (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- TDRD6 | c.*592G>C | 3'UTR (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- TDRP | c.*53C>T | 3'UTR (SNP) | VAF 10/21 reads (48%) | catalogued as rs1177775923; called by muse, mutect2, varscan2
- TEDDM1 | c.-161G>C | 5'UTR (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- TENT5C | c.*4229_*4265del | 3'UTR (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel
- TFAM | c.*4111G>A | 3'UTR (SNP) | VAF 26/61 reads (43%) | catalogued as rs1344566867; called by muse, mutect2, varscan2
- THSD7A | c.-134C>T | 5'UTR (SNP) | VAF 25/176 reads (14%) | catalogued as rs1203028116; called by muse, mutect2, varscan2
- TIMM8A | c.132+279G>A | Intron (SNP) | VAF 19/20 reads (95%) | called by mutect2, varscan2
- TLN2 | c.*1854C>G | 3'UTR (SNP) | VAF 53/103 reads (51%) | called by muse, mutect2, varscan2
- TMCO5A | c.*20G>C | 3'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- TMED7-TICAM2 | c.*1587C>T | 3'UTR (SNP) | VAF 54/113 reads (48%) | called by muse, mutect2, varscan2
- TMEM154 | c.*4565A>G | 3'UTR (SNP) | VAF 49/118 reads (42%) | called by muse, varscan2
- TMEM154 | c.*4564T>A | 3'UTR (SNP) | VAF 50/118 reads (42%) | called by muse, varscan2
- TMEM229A | c.*676G>A | 3'UTR (SNP) | VAF 56/96 reads (58%) | called by muse, mutect2, varscan2
- TMEM229B | c.*675G>A | 3'UTR (SNP) | VAF 39/84 reads (46%) | catalogued as rs987095966; called by muse, mutect2, varscan2
- TMEM268 | c.*2158G>T | 3'UTR (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- TMEM8B | c.*958C>T | 3'UTR (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- TONSL | c.3559+48G>C | Intron (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- TOX3 | c.87+27153G>A | Intron (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- TRAPPC4 | c.350+53T>C | Intron (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- TSHR | c.692+115C>G | Intron (SNP) | VAF 192/451 reads (43%) | catalogued as COSV53316661; called by muse, mutect2, varscan2
- TSLP | c.*1422G>A | 3'UTR (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- TULP4 | c.*5029C>G | 3'UTR (SNP) | VAF 45/85 reads (53%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*285C>T | 3'UTR (SNP) | VAF 47/112 reads (42%) | called by muse, mutect2
- UBIAD1 | c.*134C>T | 3'UTR (SNP) | VAF 56/125 reads (45%) | catalogued as rs957803462; called by muse, mutect2, varscan2
- UNC5D | c.-181C>T | 5'UTR (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- WDR82 | c.*918G>A | 3'UTR (SNP) | VAF 3/28 reads (11%) | catalogued as COSV99627246; called by muse, mutect2
- WEE2 | c.1393-22C>T | Intron (SNP) | VAF 51/109 reads (47%) | catalogued as COSV101187682; called by muse, mutect2, varscan2
- ZBTB38 | chr3:141447515 C>T | 3'Flank (SNP) | VAF 27/132 reads (20%) | called by muse, mutect2, varscan2
- ZFC3H1 | c.5833-60G>A | Intron (SNP) | VAF 93/193 reads (48%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.-134C>G | 5'UTR (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- ZIC1 | c.*1392del | 3'UTR (DEL) | VAF 25/61 reads (41%) | catalogued as COSV51550180; called by mutect2, pindel, varscan2
- ZNF24 | c.*2977G>A | 3'UTR (SNP) | VAF 66/127 reads (52%) | catalogued as rs1206029456; called by muse, mutect2, varscan2
- ZNF250 | c.*2343G>A | 3'UTR (SNP) | VAF 29/51 reads (57%) | called by muse, mutect2, varscan2
- ZNF282 | c.-38C>T | 5'UTR (SNP) | VAF 20/79 reads (25%) | catalogued as rs781091554; called by muse, mutect2, varscan2
- ZNF404 | chr19:43883979 T>A | 5'Flank (SNP) | VAF 83/175 reads (47%) | called by muse, mutect2, varscan2
- ZNF587B | c.1122+56C>T | Intron (SNP) | VAF 92/190 reads (48%) | called by muse, mutect2, varscan2
- ZNF626 | c.-110C>T | 5'UTR (SNP) | VAF 31/75 reads (41%) | catalogued as rs1365634923, COSV99391759; called by muse, mutect2, varscan2
- ZNF705G | c.*1579C>G | 3'UTR (SNP) | VAF 31/122 reads (25%) | catalogued as rs768957933; called by muse, mutect2
- ZNF891 | c.*573G>A | 3'UTR (SNP) | VAF 50/79 reads (63%) | called by muse, mutect2, varscan2
- ZSWIM7 | c.*1147C>T | 3'UTR (SNP) | VAF 10/49 reads (20%) | catalogued as rs947337828; called by muse, mutect2, varscan2
- ZWINT | c.*42-84G>A | Intron (SNP) | VAF 11/201 reads (5%) | called by muse, mutect2
- ZZEF1 | c.*1685C>T | 3'UTR (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
